Gene-level copy-number profile of tumor specimen HTMCP-03-06-02330-01A from CGCI case HTMCP-03-06-02330, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 42.6 years (15,573 days).
Specimen HTMCP-03-06-02330-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9500093f-45b1-4330-9edf-70cb457ddc3d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02330-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/eac664e4-79e9-4963-963f-743a4432c50c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 2: 13,783; copy number 3: 33,178; copy number 4: 6,156; copy number 5: 1,957; copy number 6: 1,608; copy number 7: 1,030; copy number 8: 665.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr22:18,400,407–18,404,206, 1 gene: PPP1R26P3.
- chr22:18,486,999–18,491,247, 1 gene (within-gene range 0–3): AC023490.2.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 741 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 679 genes, copy number 7–8 (broad region; genes not listed).
- chr14:22,163,238–22,513,998, 61 genes, copy number 8 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 8: TRAC.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
